Somatic mutation profile of tumor specimen TCGA-80-5608-01A (aliquot TCGA-80-5608-01A-31D-1945-08) from TCGA case TCGA-80-5608, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-80-5608-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2211559-06a3-477c-9f87-98abd30bca15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-80-5608-10A (Blood Derived Normal), aliquot TCGA-80-5608-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e62c7ad-6285-4329-a824-affb4f06d811

The open-access MAF lists 184 somatic variants for this specimen: 139 protein-altering or splice-affecting, 44 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 44, Nonsense Mutation 9, Splice Site 6, Frame Shift Ins 2, Intron 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RUNX1 | c.521G>A p.R174Q (on ENST00000344691 / NM_001001890.3; = p.R201Q on NM_001754.5) | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs74315450, CM992140, COSV55867719, COSV55890900; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.301C>A p.L101M (on ENST00000297504 / NM_001282291.2; = p.L84M on NM_007188.5) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV52509464; called by muse, mutect2, varscan2
- ABO | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV71743655; called by muse, mutect2, varscan2
- ACAP2 | c.1358C>G p.S453C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100462289, COSV58754307; called by muse, mutect2, varscan2
- ACSL4 | c.1769C>A p.A590D (on ENST00000340800 / NM_022977.2; = p.A549D on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV61615577; called by muse, mutect2
- ACSM2B | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as COSV61659083, COSV61659638; called by muse, mutect2, varscan2
- ACTC1 | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV51761014; called by muse, mutect2, varscan2
- ADGRG7 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.055); catalogued as COSV56300428; called by muse, mutect2, varscan2
- ALMS1 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as COSV52519832; called by muse, mutect2, varscan2
- ANKAR | c.1838A>G p.Y613C | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772172022, COSV55612848; called by muse, mutect2, varscan2
- APBB2 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55960554; called by muse, mutect2, varscan2
- ARHGAP32 | c.4779G>T p.M1593I (on ENST00000310343 / NM_001378025.1; = p.M1244I on NM_014715.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.024); catalogued as COSV59854426; called by mutect2, varscan2
- ASPM | c.8405G>T p.G2802V | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as COSV54136920; called by muse, mutect2, varscan2
- ASTN2 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as rs780254839, COSV57811460; called by muse, mutect2, varscan2
- ATM | c.9156G>C p.W3052C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53761828; called by muse, mutect2, varscan2
- ATP8B4 | c.2782-2A>T p.X928_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV52722651; called by muse, mutect2, varscan2
- AVPR1A | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV54547846; called by muse, mutect2, varscan2
- B4GALNT2 | c.396-1G>T p.X132_splice | Splice Site (SNP) | VAF 30/87 reads (34%) | catalogued as COSV55927914; called by mutect2, varscan2
- BTK | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV58123217; called by muse, varscan2
- C1orf56 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1361320516, COSV54848618; called by muse, mutect2, varscan2
- C7 | c.1634G>T p.C545F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100495795, COSV57471924; called by muse, varscan2
- CACNA1D | c.1417T>A p.S473T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55461738; called by muse, mutect2, varscan2
- CASKIN1 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58876121; called by mutect2, varscan2
- CBLN2 | c.74C>A p.P25Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV54052741; called by muse, mutect2, varscan2
- CCKBR | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV58104664; called by muse, varscan2
- CDH10 | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52579101; called by muse, mutect2, varscan2
- CDH12 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as COSV66396706, COSV66440665; called by muse, mutect2, varscan2
- CDH19 | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs749665230, COSV50968733; called by mutect2, varscan2
- CDH8 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181470, COSV54898960; called by muse, mutect2, varscan2
- CDH8 | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100181473, COSV54872659; called by muse, mutect2, varscan2
- CHRNA9 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV59574152, COSV59575686; called by muse, mutect2, varscan2
- CLTRN | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.509); catalogued as COSV66712348; called by muse, mutect2, varscan2
- CNOT1 | c.2404G>T p.D802Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV57778671; called by mutect2, varscan2
- CRNN | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV55123472; called by muse, mutect2, varscan2
- CRYBG3 | c.6590A>T p.Y2197F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.29); catalogued as COSV51715355; called by muse, mutect2, varscan2
- CTAGE1 | c.1459C>G p.P487A | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV101194651, COSV66944477; called by muse, mutect2, varscan2
- DACT1 | c.2107G>C p.G703R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV60023039; called by muse, varscan2
- DEDD | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63502630; called by muse, mutect2
- DIDO1 | c.5242C>A p.P1748T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV56625054, COSV56632326; called by muse, mutect2, varscan2
- DNAH7 | c.3936A>T p.R1312S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56781339; called by muse, mutect2, varscan2
- EPHA5 | c.2633C>A p.P878H | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56640264, COSV56650966, COSV56668199; called by muse, varscan2
- EPN2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs774000263, COSV59063202; called by muse, mutect2, varscan2
- FAM131B | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.291); catalogued as COSV58373753; called by muse, mutect2, varscan2
- FAM135B | c.669+2T>C p.X223_splice | Splice Site (SNP) | VAF 17/138 reads (12%) | catalogued as COSV52748525; called by muse, mutect2, varscan2
- FECH | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV50492363; called by muse, mutect2
- GABBR1 | c.1746G>T p.K582N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV63544219; called by mutect2, varscan2
- GCLC | c.1587G>T p.K529N (on ENST00000643939; = p.K527N on NM_001498.4) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV57597449; called by mutect2, varscan2
- GJB1 | c.571A>T p.T191S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1555937248, CM004049, COSV62139840; ClinVar: uncertain significance; called by muse, mutect2
- GPD2 | c.1936G>T p.V646F | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV60096140; called by muse, mutect2, varscan2
- H3C4 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); catalogued as COSV61912320; called by muse, mutect2, varscan2
- HBG2 | c.340G>T p.V114F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100400631; called by muse, mutect2, varscan2
- HMCN1 | c.10505G>T p.G3502V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54933471; called by mutect2, varscan2
- HOXD8 | c.534G>C p.Q178H | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV57486637; called by muse, mutect2, varscan2
- HP1BP3 | c.1142-1G>T p.X381_splice | Splice Site (SNP) | VAF 22/35 reads (63%) | catalogued as COSV56564307; called by muse, mutect2, varscan2
- HS3ST3A1 | c.721G>C p.V241L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV52378667, COSV99404539; called by muse, mutect2, varscan2
- IGLL1 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV50770276; called by mutect2, varscan2
- ITPR2 | c.830G>T p.S277I | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67274858; called by muse, mutect2
- KCNU1 | c.2180C>A p.A727D | Missense Mutation (SNP) | VAF 177/319 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs750759618, COSV67759246; called by muse, mutect2, varscan2
- KIT | c.1835T>C p.I612T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.224); catalogued as rs1322867456, COSV55417679; called by muse, mutect2, varscan2
- KLHL35 | c.1411C>A p.L471M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV66219678; called by mutect2, varscan2
- KRT20 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV51425990; called by muse, mutect2, varscan2
- LAMB1 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99740694; called by mutect2, varscan2
- LAMB4 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52728811; called by muse, mutect2, varscan2
- LPA | c.3208G>C p.V1070L | Missense Mutation (SNP) | VAF 178/473 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as COSV60303782, COSV60309681; called by muse, mutect2, varscan2
- LRP1B | c.12386A>G p.Y4129C | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67255579; called by muse, mutect2, varscan2
- LRRC71 | c.980A>T p.Q327L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61655929; called by mutect2, varscan2
- LYN | c.1212G>C p.K404N | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV70206322; called by muse, mutect2
- MAGEL2 | c.2609A>T p.E870V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV100045809, COSV58568748; called by muse, mutect2, varscan2
- METTL15 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs530544431, COSV57723260; called by muse, mutect2, varscan2
- MFSD4A | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV65656979; called by muse, mutect2, varscan2
- MUC5AC | c.15600C>G p.I5200M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.872); catalogued as COSV100611435; called by muse, mutect2
- MYH8 | c.4094C>A p.S1365Y | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67971024; called by muse, mutect2, varscan2
- MYLK | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs559933360, COSV60620092; called by muse, mutect2, varscan2
- NDST1 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.426); catalogued as COSV55790283; called by muse, mutect2, varscan2
- NLRP3 | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1558192397, COSV60227696, COSV60229997; called by mutect2, varscan2
- NPR1 | c.1291C>A p.Q431K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64143181; called by mutect2, varscan2
- OR10J3 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV59955463; called by muse, mutect2, varscan2
- OR2T34 | c.619T>A p.C207S | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV60901753; called by muse, mutect2
- OR5F1 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV53545459, COSV53546047; called by muse, mutect2, varscan2
- OR5T2 | c.798G>C p.K266N | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV57590635; called by muse, varscan2
- OR8J3 | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV56883675; called by muse, mutect2, varscan2
- PARVG | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV63562682; called by mutect2, varscan2
- PCDHA1 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs1206688440, COSV65376421; called by mutect2, varscan2
- PCDHA12 | c.1504C>A p.H502N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs782283591, COSV100250333; called by muse, mutect2, varscan2
- PCDHAC1 | c.2652C>A p.Y884* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV53846691, COSV53865592; called by muse, mutect2, varscan2
- PCDHB8 | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV99176925; called by mutect2, varscan2
- PCDHGA3 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.014); catalogued as rs752062170, COSV53935116; called by mutect2, varscan2
- PDE6B | c.469-1G>T p.X157_splice | Splice Site (SNP) | VAF 34/88 reads (39%) | catalogued as COSV55329998; called by muse, mutect2, varscan2
- PMFBP1 | c.2168A>T p.E723V (on ENST00000537465; = p.E718V on NM_031293.3) | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52830630; called by mutect2, varscan2
- PTCHD3 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV71257226; called by mutect2, varscan2
- PTPRC | c.1405C>A p.R469S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.721); catalogued as COSV100721929, COSV61411009; called by muse, mutect2, varscan2
- PWWP3B | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV61801420; called by muse, mutect2, varscan2
- PXDNL | c.2714G>C p.R905P | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs201163014, COSV62496662; called by mutect2, varscan2
- RAI1 | c.5632T>A p.Y1878N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55397840; called by muse, mutect2, varscan2
- RASAL2 | c.1999G>T p.D667Y | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV62721480; called by muse, mutect2, varscan2
- RC3H2 | c.2524G>T p.G842C | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV61802197; called by muse, mutect2, varscan2
- RND3 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV55725361, COSV55725713; called by muse, mutect2, varscan2
- RPL3L | c.980A>T p.N327I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV51908123; called by muse, mutect2, varscan2
- RYR2 | c.5416G>T p.A1806S | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV63708456; called by muse, mutect2, varscan2
- RYR2 | c.12580G>T p.E4194* | Nonsense Mutation (SNP) | VAF 38/142 reads (27%) | catalogued as COSV63680501, COSV63708467; called by muse, mutect2, varscan2
- SLC12A3 | c.2580G>T p.K860N (on ENST00000563236 / NM_001126108.2; = p.K869N on NM_000339.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV52635559, COSV52638338; called by mutect2, varscan2
- SLC26A4 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV55918685; called by muse, mutect2, varscan2
- SLC39A12 | c.1306G>T p.G436W | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1366886781, COSV66201864; called by muse, mutect2, varscan2
- SLC8A1 | c.2737C>A p.L913I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.388); catalogued as COSV60493897; called by mutect2, varscan2
- SPHKAP | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 40/137 reads (29%) | catalogued as COSV60891598; called by mutect2, varscan2
- SPOPL | c.1015G>T p.G339W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54515969; called by muse, mutect2, varscan2
- SPPL2C | c.2032A>T p.M678L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100234035; called by muse, mutect2, varscan2
- STK11 | c.184A>T p.K62* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as CM1313842, COSV58824902; called by muse, mutect2, varscan2
- STK33 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV59407943; called by muse, mutect2, varscan2
- SULT1A2 | c.324C>G p.H108Q | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1453410006, COSV57682901; called by muse, mutect2, varscan2
- SYNE1 | c.13985A>T p.K4662M (on ENST00000367255 / NM_182961.4; = p.K4591M on NM_033071.3) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54920246, COSV55077502; called by muse, mutect2, varscan2
- SYT11 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV64175819; called by muse, mutect2, varscan2
- TAF1 | c.472G>T p.E158* (on ENST00000373790 / NM_138923.4; = p.V158L on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV52122934; called by mutect2, varscan2
- TCHHL1 | c.1910G>T p.G637V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100916570, COSV64287252; called by muse, mutect2, varscan2
- TENM1 | c.4045C>A p.Q1349K | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.218); catalogued as rs1046691886, COSV64440824; called by muse, mutect2, varscan2
- TIGIT | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.188); catalogued as COSV67329395; called by muse, mutect2, varscan2
- TMEM169 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761143727, COSV55265996; called by muse, mutect2, varscan2
- TMEM171 | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.54); catalogued as rs777009505, COSV55131570; called by muse, mutect2, varscan2
- TPTE | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs751216471; called by muse, mutect2, varscan2
- TRPA1 | c.994G>T p.G332* | Nonsense Mutation (SNP) | VAF 32/64 reads (50%) | catalogued as COSV51571933; called by muse, mutect2, varscan2
- TRPS1 | c.3110T>A p.I1037N (on ENST00000220888 / NM_001330599.2; = p.I1050N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV55257896; called by muse, mutect2
- TRPS1 | c.139G>T p.D47Y (on ENST00000220888 / NM_001330599.2; = p.D60Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); catalogued as COSV55257907; called by muse, mutect2, varscan2
- TRPV6 | c.1524C>G p.F508L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63893254, COSV63893634; called by muse, varscan2
- TTI1 | c.1907A>T p.Q636L | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV65063043; called by muse, mutect2, varscan2
- UGT1A10 | c.832C>A p.H278N | Missense Mutation (SNP) | VAF 87/337 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV60849491; called by muse, mutect2, varscan2
- UXS1 | c.986A>C p.H329P | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV51681609; called by muse, mutect2, varscan2
- VN1R1 | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV58091631; called by muse, mutect2, varscan2
- VTN | c.759C>A p.N253K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs782405279, COSV56873063, COSV56874739; called by muse, mutect2, varscan2
- VWA8 | c.3365-2A>T p.X1122_splice | Splice Site (SNP) | VAF 49/86 reads (57%) | catalogued as COSV64999719; called by muse, mutect2, varscan2
- ZNF227 | c.1259C>A p.A420D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.527); catalogued as COSV57313473; called by muse, mutect2, varscan2
- ZNF23 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs1012520477, COSV61841599; called by muse, mutect2, varscan2
- ABCB8 | c.1434_1439del p.F479_S480del (on ENST00000297504 / NM_001282291.2; = p.F462_S463del on NM_007188.5) | In Frame Del (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel, varscan2
- IGHA2 | c.690C>A p.N230K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA4 | c.675_676insA p.P226Tfs*4 | Frame Shift Ins (INS) | VAF 36/120 reads (30%) | called by mutect2, pindel*, varscan2
- LTBP4 | c.2011G>A p.D671N (on ENST00000308370 / NM_001042544.1; = p.D634N on NM_003573.2) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- MUC16 | c.36850T>G p.L12284V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.237); called by muse, varscan2
- OR5M8 | c.236dup p.M80Dfs*31 | Frame Shift Ins (INS) | VAF 31/111 reads (28%) | called by mutect2, pindel, varscan2
- PGAP4 | c.382_383delinsA p.L128Ifs*23 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | called by pindel, varscan2*
- ASTN2 | c.639C>A p.L213= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs7856949; called by muse, varscan2
- B3GAT1 | c.223C>A p.R75= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV56996355, COSV57000249; called by muse, mutect2, varscan2
- BFSP2 | c.262C>T p.L88= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV56591337; called by muse, mutect2, varscan2
- CASP8AP2 | c.4233G>T p.V1411= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV52749369; called by muse, mutect2, varscan2
- CENPF | c.9069C>T p.S3023= | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as COSV65278438; called by muse, mutect2, varscan2
- CERKL | c.798C>A p.A266= (on ENST00000339098 / NM_001030311.2; = p.A240= on NM_201548.5) | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV59212746; called by muse, mutect2, varscan2
- CNTN2 | c.1344C>T p.A448= | Silent (SNP) | VAF 42/157 reads (27%) | catalogued as rs778178054, COSV59350793, COSV59350837, COSV59352319; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP5 | c.1143C>T p.P381= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs769673214, COSV70477851, COSV70501264; called by muse, mutect2, varscan2
- CPNE5 | c.1695G>T p.P565= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV55199348; called by muse, mutect2, varscan2
- CRACDL | c.426G>T p.G142= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV67409844; called by muse, mutect2, varscan2
- DRD5 | c.1281C>T p.N427= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV58579093; called by mutect2, varscan2
- ERBB2 | c.1203G>A p.E401= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV54077143, COSV54080592; called by muse, mutect2, varscan2
- FAM216A | c.661C>T p.L221= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV62195409; called by muse, mutect2, varscan2
- FRMD4A | c.741T>C p.D247= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1285480977, COSV52734202; called by muse, mutect2, varscan2
- GLI3 | c.3318A>T p.A1106= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs148780793, COSV67894003; called by muse, mutect2, varscan2
- GYS1 | c.927G>T p.R309= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as COSV54404964; called by muse, varscan2
- HEY2 | c.690G>A p.T230= | Silent (SNP) | VAF 40/274 reads (15%) | catalogued as COSV64240015; called by muse, mutect2, varscan2
- KIDINS220 | c.807G>T p.G269= | Silent (SNP) | VAF 83/235 reads (35%) | catalogued as COSV56758133; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1665C>T p.G555= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs776501300; called by mutect2, varscan2
- MMP12 | c.879C>A p.T293= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs571598878, COSV100404907, COSV100404950; called by muse, varscan2
- NACA | c.162G>C p.A54= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV63272327; called by muse, mutect2, varscan2
- OR10AG1 | c.378G>T p.V126= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV56632374, COSV56634418; called by muse, mutect2, varscan2
- OR1D2 | c.75G>T p.R25= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs770626037, COSV58922335; called by muse, mutect2, varscan2
- OR5I1 | c.202C>T p.L68= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1235590206, COSV56888783; called by muse, mutect2, varscan2
- OR8B3 | c.660C>T p.F220= | Silent (SNP) | VAF 44/220 reads (20%) | catalogued as COSV63542201; called by muse, mutect2, varscan2
- PCDH15 | c.3426A>G p.P1142= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV57378368; called by muse, mutect2
- PCK1 | c.834G>A p.K278= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV60130537; called by muse, mutect2, varscan2
- PGBD2 | c.1206C>A p.V402= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV61400616, COSV61400954; called by mutect2, varscan2
- PHTF1 | c.777C>T p.C259= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV63368699; called by muse, mutect2, varscan2
- PPM1H | c.378C>T p.P126= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV57378387; called by muse, mutect2, varscan2
- PTPRD | c.2583C>G p.G861= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV61975379; called by muse, mutect2, varscan2
- RREB1 | c.2922A>T p.A974= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV58563817; called by muse, mutect2, varscan2
- RRP8 | c.612A>T p.P204= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV54450527; called by muse, mutect2, varscan2
- SERPINA3 | c.405G>A p.L135= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs377149330; called by mutect2, varscan2
- SS18L1 | c.240G>T p.T80= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100065096, COSV59213030; called by mutect2, varscan2
- SYNJ1 | c.2334C>T p.N778= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs753774552, COSV59155197; called by mutect2, varscan2
- TMPRSS9 | c.207C>A p.T69= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100211364; called by muse, varscan2
- TTBK1 | c.3120C>A p.I1040= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52495714; called by mutect2, varscan2
- VPS54 | c.345A>G p.E115= | Silent (SNP) | VAF 43/141 reads (30%) | catalogued as COSV55444429; called by muse, mutect2, varscan2
- WDR27 | c.561G>C p.R187= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs770140682, COSV100359889, COSV61214765; called by muse, mutect2, varscan2
- ZBTB45 | c.837T>G p.A279= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV54021564; called by muse, mutect2, varscan2
- ZNF217 | c.2499C>T p.A833= | Silent (SNP) | VAF 78/163 reads (48%) | catalogued as COSV56601259; called by muse, mutect2, varscan2
- ZNF532 | c.3198G>A p.S1066= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as rs199973703, COSV60174205; called by muse, mutect2, varscan2
- ZNF71 | c.1104G>C p.S368= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs909072518, COSV60146261, COSV60149746; called by muse, mutect2, varscan2
- H2BP2 | n.1061+620C>A | Intron (SNP) | VAF 6/9 reads (67%) | called by mutect2, varscan2
